Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70H, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70H-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology	Final Results
--------------------	---------------

Surgical Pathology
CASE NUMBER:
DIAGNOSIS:

Adrenal gland, left (adrenalectomy):
- Pheochromocytoma; see note.

NOTE: Immunohistochemical staining is performed on tissue blocks "1F" and "1M". The lesional cells of pheochromocytoma stain diffusely positive for S-100, NSE, Synatophysin, and CD56. Some of the tissue sections also show adrenal cortical tissue.

The immunoperoxidase tests performed here were developed and their performance characteristics determined by the _____ of the Laboratory of Pathology, _____. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: _____ man with a left adrenal mass and elevated metanephrines
Requestor Name
Requestor Phone/Pager:
Specimen Taken For Protocol: 01 - Yes
Allocate Order to
Protocol:

PROCEDURE: Operative Findings: large left sided adrenal mass not invading surrounding structures
Post-Operative Diagnosis: pheochromocytoma
Pre-Operative Diagnosis: pheochromocytoma

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, LEFT

GROSS DESCRIPTION: Received is a 57.5-gram piece of yellow/red tissue measuring 7.6 x 6.8 x 6.9 cm and labeled as "left adrenal gland". There is a flat, yellow/brown tissue grossly consistent with normal adrenal (4.1 x 1.8 x 0.6 cm) along one aspect of the specimen, and a brown/red soft nodule measuring 5.2 x 4.6 x 2.9 cm occupying the rest of the specimen. The specimen is entirely inked in black and the nodule is bisected to reveal a tan/red cut surface with punctate hemorrhages, and a faint rim of grossly normal-appearing adrenal tissue at the periphery. 30% of the nodule was procured for _____. Two small fragments measuring 0.4 x 0.2 x 0.2 cm in aggregate was procured for (Nunc tubes 415 and 416). The area of normal-appearing adrenal tissue is bivalved to reveal a golden-yellow ribbon of tissue grossly

[page 2 of 2]
Surgical Pathology

Final Results

consistent with the normal adrenal gland. Approximately 40% was
procured for A small fragment measuring 0.2 x 0.2 x
0.1 cm was procured for The
procurement description was provided by on

In Surgical Pathology, the specimen is received consistent with
the above description. The specimen weighs 45 grams. The procurement
surface is variegated and brown. Approximately 80% of the specimen is
submitted in cassettes for permanent processing.

Gross dictated by

No consultants

#

#

Source: NCI Genomic Data Commons file 19c7c5db-d2e7-4b12-aa9b-05e8ace27bfd (TCGA-QR-A70H.638243F5-83B3-4DD7-AA30-FC2217E8869F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).